Somatic mutation profile of tumor specimen TCGA-VM-A8CD-01A (aliquot TCGA-VM-A8CD-01A-11D-A36O-08) from TCGA case TCGA-VM-A8CD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,200 days).
Specimen TCGA-VM-A8CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 603869cd-c1b1-4ef4-9928-d0f9dc177f3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8CD-10A (Blood Derived Normal), aliquot TCGA-VM-A8CD-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/680a7aa7-529f-4c87-8cd8-674e335beeee

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Nonstop Mutation 1, 5'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs121909241, CM045431, CM063078, CM074468, COSV64288421, COSV64288528, COSV64293854; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by mutect2, varscan2
- ANK2 | c.4568C>T p.T1523I | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100004718, COSV52162927; called by mutect2, varscan2
- CACNG3 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1047741779, COSV50064727; called by mutect2, varscan2
- CFH | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.166); catalogued as COSV62776162; called by muse, mutect2, varscan2
- CUX1 | c.164C>T p.P55L (on ENST00000292535 / NM_181552.4; = p.P66L on NM_001913.5) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213438024, COSV99473451; called by mutect2, varscan2
- ETFRF1 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100350802; called by mutect2, varscan2
- HOXD4 | c.767A>G p.*256Wext*81 | Nonstop Mutation (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100107095; called by muse, mutect2, varscan2
- IGHM | c.969G>T p.G323= | Splice Region (SNP) | VAF 5/12 reads (42%) | catalogued as rs1555377848; called by mutect2, varscan2
- MCTP1 | c.2866T>C p.Y956H | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs141609728; called by mutect2, varscan2
- NPAS3 | c.992A>C p.H331P (on ENST00000356141 / NM_001164749.2; = p.H299P on NM_022123.3) | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs769202642, COSV100640783; called by mutect2, varscan2
- NSMCE3 | c.600C>G p.D200E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.78); PolyPhen benign (0.048); catalogued as COSV99723940; called by muse, mutect2, varscan2
- PLXNB1 | c.4759C>T p.R1587W | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004255185, COSV56488379; called by muse, mutect2, varscan2
- SON | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99280257; called by mutect2, varscan2
- ZNFX1 | c.3076C>T p.H1026Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871042; called by mutect2, varscan2
- NF1 | c.215del p.G72Efs*13 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- CDHR5 | c.1803A>G p.A601= (on ENST00000358353 / NM_001171968.2; = p.A607= on NM_021924.5) | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as COSV100363904; called by mutect2, varscan2
- LLGL2 | c.1641C>T p.A547= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs532394871, COSV99390653; called by mutect2, varscan2
- NCR3 | c.531G>A p.P177= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs775013182, COSV99279236; called by mutect2, varscan2
- POLQ | c.7513C>A p.R2505= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99953170; called by mutect2, varscan2
- PTPRM | c.4302C>G p.L1434= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs1330490611, COSV100161292; called by mutect2, varscan2
- RPAP3 | c.1482A>G p.A494= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV99139618; called by mutect2, varscan2
- STAR | c.126C>T p.G42= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99379257; called by mutect2, varscan2
- AP000769.5 | chr11:65500589 A>G | 5'Flank (SNP) | VAF 58/109 reads (53%) | catalogued as rs1366476103; called by mutect2, varscan2
